Surgical pathology report (de-identified scan), TCGA case TCGA-36-1580, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site BC Cancer Agency, specimen TCGA-36-1580-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Consultation Report

TCGA-36-1580

Case Number:

Collect Date:

Receive Date:

Date Reported:

Patient's Name:

MRN:

PHN:

DOB/Gender:

Ordering Physician:

Final Diagnosis:

1. Omentum: Omental cake showing high grade papillary serous carcinoma, compatible with peritoneal, ovarian, or tubal origin, FIGO tumor grade 3/3 (both specimens)

2. Abdominal ascitic fluid (): Positive for numerous cell clusters of high grade papillary serous carcinoma

Clinical History as Provided by Submitting Physician:

A. Omentum-frozen

B. Omentum

Specimens Received:

A: omentum

B: omentum

Gross Description:

Specimen is received in two containers both labelled with the patient's name.

Container "A" is labelled "omentum" and consists of a fragment of fatty tissue measuring 1.0 cm in diameter. Provisional diagnosis: Poorly differentiated papillary serous carcinoma. Submitted in toto as "A1", frozen section block, "A2" rest of the specimen.

Container "B" is labelled "omentum" and consists of a greater omentum measuring 13.0 x 8.5 x 3.0 cm weighing 140 grams. Specimen consists of firm nodule predominantly occupying omentum. Cross section of the nodule shows tan white fibrous structure with focal hemorrhage and necrosis. Representative section submitted as "B1"- "B4".

Intraoperative Consultation:

FSA1:

GROSS:

Fragments of greyish white friable tissue, 1.0 cm in diameter

PROVISIONAL DIAGNOSIS:

Poorly differentiated papillary serous carcinoma.

Source: NCI Genomic Data Commons file c1edfe91-58e6-4d00-a80d-a7e1f640446b (TCGA-36-1580.A647E4DA-8579-4848-B545-BC857DB85D98.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).